Gene-level copy-number profile of tumor specimen C3L-00603-02 from CPTAC case C3L-00603, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 72.3 years (26,424 days).
Specimen C3L-00603-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7672cfda-a898-44e7-a2fb-9c46c07d52c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00603-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/a3afee9c-9bc4-4a6b-a8c6-d5bdd018a505

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 665; copy number 1: 17,360; copy number 2: 36,292; copy number 3: 2,464; copy number 4: 2,078; copy number 5: 20; copy number 6: 14; copy number 8: 3; copy number 13: 11.

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr3:11,488,300–11,529,755, 2 genes (within-gene range 0–1): AC026185.1, AC022001.1.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr9:21,106,543–31,645,160, 124 genes (broad region; genes not listed).
- chr14:43,990,539–44,911,863, 15 genes (within-gene range 0–1): LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3.
- chr14:60,639,216–60,658,259, 2 genes: SALRNA1, SIX1.
- chr14:102,770,040–102,933,596, 4 genes (within-gene range 0–1): AL132801.1, TRAF3, RNU6-1316P, AMN.
- chr14:102,933,574–102,937,177, 1 gene (within-gene range 0–1): AL117209.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:13,299,184–13,601,929, 3 genes, copy number 8: LINC02093, HS3ST3A1, MIR548H3.
- chr17:18,450,244–18,475,920, 4 genes, copy number 6 (within-gene range 6–7): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:29,560,547–29,641,702, 10 genes, copy number 6 (within-gene range 2–6): ABHD15, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, AC104564.1, RNU6-920P.
- chr19:32,675,848–33,382,686, 31 genes, copy number 5–13 (within-gene range 3–13): RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG.

Autosomal genes at a single copy (total copy number 1): 15,023. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
